Somatic mutation profile of tumor specimen TCGA-DX-A1L0-01A (aliquot TCGA-DX-A1L0-01A-11D-A24N-09) from TCGA case TCGA-DX-A1L0, project TCGA-SARC (Sarcoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Dedifferentiated liposarcoma; Tissue or organ of origin: Retroperitoneum; Age at diagnosis: 58.7 years (21,434 days).
Specimen TCGA-DX-A1L0-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) bcc2900d-ee66-47e9-8df5-2153ddb44419.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DX-A1L0-10A (Blood Derived Normal), aliquot TCGA-DX-A1L0-10A-01D-A24N-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f8a459d5-f359-4cf4-b340-843474ad121a

The open-access MAF lists 89 somatic variants for this specimen: 65 protein-altering or splice-affecting, 18 silent, 6 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 59, Silent 18, Nonsense Mutation 3, Intron 3, Splice Site 2, 3'Flank 2, Frame Shift Del 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AKR1B10 | c.73C>G p.L25V | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV104422318; called by muse, mutect2
- ATP9B | c.1030G>C p.G344R | Missense Mutation (SNP) | VAF 76/332 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100303929; called by muse, mutect2, varscan2
- BCAN | c.2328C>G p.S776R | Missense Mutation (SNP) | VAF 26/77 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV61256069; called by muse, mutect2, varscan2
- CAB39 | c.680G>T p.R227I | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99299676; called by mutect2, varscan2
- CPAMD8 | c.1916C>T p.S639L (on ENST00000651564; = p.S592L on NM_015692.5) | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen benign (0.024); catalogued as rs758309902; called by muse, mutect2, varscan2
- CUBN | c.10764+1G>T p.X3588_splice | Splice Site (SNP) | VAF 18/33 reads (55%) | catalogued as COSV100912219; called by muse, mutect2, varscan2
- DNAH3 | c.3668C>T p.S1223L | Missense Mutation (SNP) | VAF 28/31 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.968); catalogued as rs370381549, COSV99766410; called by muse, mutect2, varscan2
- DOCK8 | c.3098C>A p.A1033D | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT tolerated (0.12); PolyPhen benign (0.065); catalogued as COSV66624452; called by muse, mutect2, varscan2
- DYRK2 | c.1340A>G p.D447G (on ENST00000344096 / NM_006482.3; = p.D374G on NM_003583.4) | Missense Mutation (SNP) | VAF 279/918 reads (30%) | SIFT deleterious (0.02); PolyPhen benign (0.045); catalogued as rs1460296462; called by muse, mutect2, varscan2
- ERMN | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.506); catalogued as rs374683748, COSV68075295; called by muse, mutect2, varscan2
- F11R | c.388+1G>T p.X130_splice | Splice Site (SNP) | VAF 122/174 reads (70%) | catalogued as COSV99230858; called by muse, varscan2
- FLT4 | c.1924C>T p.R642C | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.697); catalogued as COSV56101801; called by muse, mutect2, varscan2
- KIR3DL1 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 52/141 reads (37%) | SIFT tolerated (0.06); PolyPhen benign (0.329); catalogued as COSV100428350; called by muse, mutect2
- MPO | c.142G>A p.G48S | Missense Mutation (SNP) | VAF 10/37 reads (27%) | SIFT tolerated (0.7); PolyPhen benign (0.019); catalogued as rs200249653; called by muse, mutect2, varscan2
- OR10A7 | c.924A>T p.K308N | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.16); PolyPhen benign (0.001); catalogued as COSV58279610; called by muse, mutect2, varscan2
- OR4A15 | c.542C>T p.P181L | Missense Mutation (SNP) | VAF 45/128 reads (35%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.973); catalogued as rs1465313972, COSV59033920, COSV59036784; called by muse, mutect2, varscan2
- PAPOLG | c.1716G>C p.K572N | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.5); PolyPhen benign (0.065); catalogued as COSV99474523; called by muse, mutect2, varscan2
- PRAMEF4 | c.740C>A p.S247Y | Missense Mutation (SNP) | VAF 59/207 reads (29%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.704); catalogued as COSV99339586; called by muse, varscan2
- PRLR | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 49/166 reads (30%) | SIFT tolerated (0.28); PolyPhen benign (0.18); catalogued as COSV51498790; called by muse, mutect2, varscan2
- PROS1 | c.1237C>A p.L413I | Missense Mutation (SNP) | VAF 13/40 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV67776765; called by muse, mutect2, varscan2
- PTPRF | c.3526C>T p.R1176W | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.634); catalogued as rs368885602; called by muse, varscan2
- RTP2 | c.588C>G p.F196L | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.978); catalogued as COSV64078812, COSV64079133; called by muse, mutect2, varscan2
- TDRD1 | c.1240G>A p.D414N | Missense Mutation (SNP) | VAF 13/28 reads (46%) | SIFT tolerated (0.1); PolyPhen benign (0.027); catalogued as rs909451021, COSV99314675; called by muse, mutect2, varscan2
- UGT2A3 | c.1054T>A p.Y352N | Missense Mutation (SNP) | VAF 6/78 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99279678; called by muse, mutect2
- ZNF215 | c.67G>C p.E23Q | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as COSV99549343; called by muse, mutect2, varscan2
- AFF3 | c.2197G>C p.D733H | Missense Mutation (SNP) | VAF 19/77 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by muse, mutect2, varscan2
- ATOH1 | c.508C>T p.R170C | Missense Mutation (SNP) | VAF 10/63 reads (16%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); called by muse, mutect2, varscan2
- ATP1A4 | c.250G>A p.G84R | Missense Mutation (SNP) | VAF 42/229 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ATP1A4 | c.378G>C p.Q126H | Missense Mutation (SNP) | VAF 26/192 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- BPIFB4 | c.1672A>T p.N558Y | Missense Mutation (SNP) | VAF 22/115 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- CCDC181 | c.1339G>C p.G447R (on ENST00000367806 / NM_001300969.1; = p.G446R on NM_021179.2) | Missense Mutation (SNP) | VAF 11/49 reads (22%) | SIFT tolerated (0.54); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- CDH22 | c.175C>T p.R59C | Missense Mutation (SNP) | VAF 16/24 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CRYGS | c.527T>C p.I176T | Missense Mutation (SNP) | VAF 17/48 reads (35%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.912); called by muse, mutect2, varscan2
- CSMD1 | c.2678G>C p.R893T (on ENST00000520002; = p.R892T on NM_033225.6) | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- DDX1 | c.1883A>C p.Y628S | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by muse, mutect2, varscan2
- DNAH5 | c.11930del p.N3977Tfs*54 | Frame Shift Del (DEL) | VAF 27/56 reads (48%) | called by pindel, varscan2
- DUSP29 | c.595C>T p.Q199* | Nonsense Mutation (SNP) | VAF 10/34 reads (29%) | called by muse, mutect2, varscan2
- EML1 | c.2015C>G p.S672C | Missense Mutation (SNP) | VAF 25/133 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.364); called by muse, varscan2
- EPHB1 | c.1663T>G p.S555A | Missense Mutation (SNP) | VAF 33/79 reads (42%) | SIFT tolerated (0.6); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- F11R | c.469G>C p.D157H | Missense Mutation (SNP) | VAF 422/458 reads (92%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.942); called by muse, varscan2
- GRIP1 | c.1030G>T p.G344W | Missense Mutation (SNP) | VAF 47/224 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.944); called by muse, mutect2, varscan2
- GRIP1 | c.238G>T p.V80L | Missense Mutation (SNP) | VAF 17/235 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- IL1R1 | c.1270T>C p.F424L | Missense Mutation (SNP) | VAF 27/90 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, varscan2
- ITPR2 | c.3041C>T p.S1014F | Missense Mutation (SNP) | VAF 31/49 reads (63%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- ITPRIPL2 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 6/16 reads (38%) | SIFT deleterious (0.03); PolyPhen benign (0.201); called by muse, mutect2, varscan2
- KLF13 | c.821G>A p.R274H | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.925); called by muse, mutect2, varscan2
- LRRN3 | c.142A>G p.M48V | Missense Mutation (SNP) | VAF 18/55 reads (33%) | SIFT tolerated (0.18); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- MTG2 | c.800A>G p.H267R | Missense Mutation (SNP) | VAF 16/57 reads (28%) | SIFT tolerated (0.12); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- MYO1F | c.1999T>A p.Y667N | Missense Mutation (SNP) | VAF 48/112 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.892); called by muse, mutect2, varscan2
- OLFML2B | c.654C>G p.I218M | Missense Mutation (SNP) | VAF 20/79 reads (25%) | SIFT tolerated (0.58); PolyPhen benign (0.107); called by muse, mutect2, varscan2
- OR5V1 | c.349G>A p.A117T | Missense Mutation (SNP) | VAF 21/26 reads (81%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.55); called by muse, mutect2, varscan2
- OXR1 | c.872A>T p.D291V (on ENST00000442977 / NM_001198532.1; = p.D290V on NM_018002.3) | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.432); called by mutect2, varscan2
- PAFAH2 | c.628A>C p.N210H | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- PLB1 | c.2551A>G p.K851E | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- PNLIPRP3 | c.1305A>T p.E435D | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.014); called by muse, mutect2
- PRKDC | c.9220C>T p.Q3074* | Nonsense Mutation (SNP) | VAF 16/65 reads (25%) | called by muse, mutect2, varscan2
- PROM1 | c.1094A>G p.N365S | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.395); called by muse, mutect2, varscan2
- PRRC2B | c.2389T>G p.F797V | Missense Mutation (SNP) | VAF 26/75 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- RC3H1 | c.888A>T p.L296F | Missense Mutation (SNP) | VAF 8/111 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- RP1 | c.5480C>G p.S1827* | Nonsense Mutation (SNP) | VAF 7/31 reads (23%) | called by muse, mutect2, varscan2
- SLC5A11 | c.903C>A p.N301K | Missense Mutation (SNP) | VAF 12/46 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, varscan2
- SLITRK1 | c.1410G>A p.M470I | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.459); called by muse, mutect2, varscan2
- SV2C | c.2054G>A p.G685E | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TARS3 | c.1870G>C p.D624H | Missense Mutation (SNP) | VAF 9/52 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); called by muse, mutect2, varscan2
- TMEM132E | c.1867G>A p.A623T (on ENST00000321639; = p.A713T on NM_001304438.2) | Missense Mutation (SNP) | VAF 34/77 reads (44%) | SIFT tolerated (1); PolyPhen benign (0.009); called by muse, mutect2, varscan2
- ATP9B | c.3045C>T p.I1015= | Silent (SNP) | VAF 34/127 reads (27%) | called by muse, mutect2, varscan2
- CBLN2 | c.615C>G p.G205= | Silent (SNP) | VAF 6/14 reads (43%) | called by muse, mutect2, varscan2
- COLQ | c.681A>G p.R227= | Silent (SNP) | VAF 34/217 reads (16%) | called by muse, varscan2
- EML1 | c.2088C>A p.I696= | Silent (SNP) | VAF 12/92 reads (13%) | catalogued as COSV51752479; called by muse, varscan2
- EP300 | c.5463A>G p.R1821= | Silent (SNP) | VAF 5/36 reads (14%) | called by muse, mutect2, varscan2
- HMCN1 | c.1629C>T p.I543= | Silent (SNP) | VAF 34/171 reads (20%) | catalogued as COSV54909695; called by muse, mutect2, varscan2
- HMOX2 | c.870G>C p.V290= | Silent (SNP) | VAF 76/92 reads (83%) | called by muse, mutect2, varscan2
- IRS4 | c.12C>T p.C4= | Silent (SNP) | VAF 18/31 reads (58%) | called by muse, mutect2, varscan2
- ITPR2 | c.2799C>A p.L933= | Silent (SNP) | VAF 76/120 reads (63%) | catalogued as COSV67264806; called by muse, varscan2
- KCNH3 | c.1866C>G p.V622= | Silent (SNP) | VAF 25/56 reads (45%) | called by muse, mutect2, varscan2
- LRRC10 | c.744C>T p.D248= | Silent (SNP) | VAF 62/1600 reads (4%) | called by muse, mutect2
- LRRC8E | c.465G>A p.K155= | Silent (SNP) | VAF 20/67 reads (30%) | catalogued as rs1281174062; called by muse, mutect2, varscan2
- P2RY4 | c.405G>A p.L135= | Silent (SNP) | VAF 12/28 reads (43%) | called by muse, mutect2, varscan2
- PASK | c.3717C>T p.R1239= | Silent (SNP) | VAF 27/38 reads (71%) | called by muse, mutect2, varscan2
- RANBP17 | c.102C>G p.L34= | Silent (SNP) | VAF 7/57 reads (12%) | called by muse, mutect2, varscan2
- SLC44A1 | c.870C>T p.L290= | Silent (SNP) | VAF 36/169 reads (21%) | called by muse, mutect2, varscan2
- SMPDL3B | c.720G>C p.G240= | Silent (SNP) | VAF 10/42 reads (24%) | called by muse, mutect2, varscan2
- SPG7 | c.432C>A p.T144= | Silent (SNP) | VAF 31/149 reads (21%) | called by muse, mutect2, varscan2
- ADGRA1 | c.4-3968G>A | Intron (SNP) | VAF 11/132 reads (8%) | catalogued as COSV101192774; called by muse, mutect2
- KSR2 | c.987-6645G>A | Intron (SNP) | VAF 36/102 reads (35%) | catalogued as rs758204394; called by muse, mutect2, varscan2
- MYL3 | chr3:46832947 G>A | 3'Flank (SNP) | VAF 31/78 reads (40%) | catalogued as rs767048114; called by muse, mutect2, varscan2
- PLEKHA8P1 | n.1590G>C | RNA (SNP) | VAF 20/79 reads (25%) | called by muse, mutect2, varscan2
- PTHLH | c.-23+185G>C | Intron (SNP) | VAF 5/79 reads (6%) | catalogued as COSV99570792; called by muse, mutect2
- RN7SL484P | chr15:99791767 G>A | 3'Flank (SNP) | VAF 36/139 reads (26%) | called by muse, mutect2, varscan2
